CCDI case PBCLBA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/9e0565e1-8b42-4506-ab18-81ffce42452a

Demographics
Sex at birth: female.

Diagnoses (1)
1. Adenoid cystic carcinoma: ICD-O-3 morphology code: 8200/3; Tissue or organ of origin: Parotid gland; Age at diagnosis: 15.7 years (5,737 days).

Biospecimens (3 samples)
- Sample 0DW8GH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DW8GT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DW8H8: Tissue type: Tumor; Specimen type: Solid Tissue.
